Somatic mutation profile of cancer-model specimen HCM-BROD-0791-C43-85N (Adherent Cell Line, passage 8; aliquot HCM-BROD-0791-C43-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0791-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.0 years (22,298 days).
Specimen HCM-BROD-0791-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99711118-a5a6-43c7-b9e2-67f49ca2b08b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0791-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0791-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d848802-adc9-4367-aee5-c8f4ec21242a

The open-access MAF lists 551 somatic variants for this specimen: 364 protein-altering or splice-affecting, 171 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 313, Silent 171, Nonsense Mutation 26, Intron 7, Frame Shift Del 6, Splice Region 5, In Frame Del 5, Splice Site 4, Frame Shift Ins 4, 5'UTR 3, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTC1 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 112/230 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs202138550, CM121576, COSV59852744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 1136/1263 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- A2ML1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs753186530, COSV55300039; called by muse, mutect2, varscan2
- ABCA9 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.216); catalogued as COSV60620561, COSV60631707; called by muse, mutect2, varscan2
- ADAMTS19 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 204/626 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1450866981; called by muse, mutect2, varscan2
- ADGRB1 | c.4172G>A p.R1391H | Missense Mutation (SNP) | VAF 172/368 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765352565; called by mutect2, varscan2
- ANKRD34C | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as rs958231841, COSV69854727; called by muse, mutect2, varscan2
- ART4 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV57453280; called by muse, varscan2
- B4GALNT2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs762429913; called by muse, mutect2
- C1orf105 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 340/437 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs760804284; called by muse, mutect2, varscan2
- CALCOCO1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 182/469 reads (39%) | catalogued as rs753475661; called by muse, mutect2, varscan2
- CBFA2T2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 136/624 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as rs368396948; called by muse, mutect2, varscan2
- CCDC112 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.416); catalogued as rs758298640; called by muse, mutect2, varscan2
- CCL1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 330/443 reads (74%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV104387821, COSV56774903; called by muse, mutect2, varscan2
- CCSER2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 138/252 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs547298513, COSV56512200; called by muse, mutect2, varscan2
- CDHR3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 115/598 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs371586125, COSV100488412; called by muse, mutect2, varscan2
- CHD3 | c.5914_5916del p.K1972del (on ENST00000330494 / NM_001005273.3; = p.K1938del on NM_005852.4) | In Frame Del (DEL) | VAF 93/233 reads (40%) | catalogued as rs768305286; called by pindel, varscan2
- CHRM5 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs140949296; called by muse, mutect2, varscan2
- CNBD2 | c.1553G>T p.R518L (on ENST00000373973 / NM_001365709.1; = p.R514L on NM_080834.4) | Missense Mutation (SNP) | VAF 141/950 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.103); catalogued as COSV62588156; called by muse, mutect2, varscan2
- CNGB1 | c.3199G>A p.V1067M | Missense Mutation (SNP) | VAF 365/367 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51907712; called by muse, mutect2, varscan2
- CNTNAP2 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62179727, COSV62201657; called by muse, mutect2, varscan2
- CPNE8 | c.834dup p.Y279Ifs*3 | Frame Shift Ins (INS) | VAF 29/147 reads (20%) | catalogued as rs945411907; called by mutect2, pindel, varscan2
- CYP2C18 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs142985033; called by muse, mutect2
- DCANP1 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 174/514 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.973); catalogued as COSV72345749; called by mutect2, varscan2
- DKK2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 132/300 reads (44%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMD | c.8609G>A p.R2870Q | Missense Mutation (SNP) | VAF 119/231 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs373481995, COSV100629636, COSV58915629; called by muse, mutect2, varscan2
- DNAH7 | c.4897G>A p.G1633R | Missense Mutation (SNP) | VAF 126/187 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1057268781, COSV56780747; called by muse, mutect2, varscan2
- DOCK3 | c.4777C>T p.L1593F | Missense Mutation (SNP) | VAF 212/315 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261675012; called by muse, mutect2, varscan2
- DOCK6 | c.2935G>A p.V979I | Missense Mutation (SNP) | VAF 214/489 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758025513; called by muse, mutect2, varscan2
- DYDC2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1554848062, COSV55471697; called by muse, mutect2, varscan2
- ELMOD1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 130/257 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs755627533; called by muse, mutect2, varscan2
- EPN3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 163/676 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780384032, COSV99276851; called by muse, mutect2, varscan2
- FAHD2B | c.22_24del p.R8del | In Frame Del (DEL) | VAF 78/306 reads (25%) | catalogued as rs754746214; called by pindel, varscan2
- FAM171A1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 152/358 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs962236898, COSV100968062, COSV65314371; called by muse, mutect2, varscan2
- FAM217B | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 304/528 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1229622849; called by muse, mutect2, varscan2
- FAT4 | c.4124C>T p.A1375V | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); catalogued as COSV67891630; called by muse, mutect2, varscan2
- FFAR2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 151/672 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs866450953; called by muse, mutect2, varscan2
- FOXN1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 465/603 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs200888774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 391/391 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMD4A | c.2427_2435del p.A816_G818del | In Frame Del (DEL) | VAF 110/329 reads (33%) | catalogued as rs759046768; called by mutect2, pindel, varscan2
- FYB2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs780506343; called by muse, mutect2, varscan2
- GLIPR1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 176/259 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56990866; called by muse, mutect2, varscan2
- GOSR2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 102/438 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1385621035; called by muse, mutect2, varscan2
- GPR4 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 397/793 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.212); catalogued as COSV59916221; called by muse, mutect2, varscan2
- GPRIN1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 185/560 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as rs746867011; called by muse, mutect2, varscan2
- GRHL1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 247/364 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61410357; called by muse, mutect2, varscan2
- GSDMA | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 126/524 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs772704853; called by muse, mutect2
- GSDMD | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 293/595 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1295876362; called by muse, mutect2, varscan2
- GSDMD | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 294/597 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1325290515, COSV52797028; called by muse, mutect2, varscan2
- H1-5 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 414/414 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1160996093; called by muse, mutect2, varscan2
- HDAC9 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1485280896, COSV67769001; called by muse, mutect2, varscan2
- HRNR | c.2374G>T p.G792C | Missense Mutation (SNP) | VAF 132/658 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as COSV64254057, COSV64255454; called by muse, mutect2, varscan2
- HYDIN | c.7564G>A p.E2522K | Missense Mutation (SNP) | VAF 670/672 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59270609; called by muse, mutect2, varscan2
- IGF2R | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1364189379; called by muse, mutect2
- IGHD6-25 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 150/478 reads (31%) | catalogued as rs567242250; called by muse, mutect2, varscan2
- IMMT | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs373215755; called by muse, mutect2, varscan2
- IZUMO2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53229372; called by muse, mutect2, varscan2
- JUP | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 127/567 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781788038; ClinVar: uncertain significance; called by muse, varscan2
- KCNC3 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 393/762 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs969082050; called by muse, mutect2, varscan2
- KCNJ10 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 145/573 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.72); catalogued as rs557187094, COSV104426516, COSV63633293; called by muse, mutect2, varscan2
- KDM4E | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 150/346 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV101482104, COSV71678276; called by muse, mutect2, varscan2
- KIAA1958 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 286/575 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as rs146666897; called by muse, mutect2, varscan2
- KIFBP | c.1265T>C p.V422A | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs960310811; called by muse, mutect2, varscan2
- KRT20 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 650/913 reads (71%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51424591; called by muse, mutect2, varscan2
- KSR2 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 204/639 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001061709; called by mutect2, varscan2
- LEUTX | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 160/331 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs1361360322; called by muse, mutect2, varscan2
- LIPF | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1048661237, COSV99490130; called by muse, mutect2, varscan2
- LPAR6 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 133/532 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.09); catalogued as COSV99923915; called by muse, mutect2, varscan2
- LRIG2 | c.1549_1550del p.L517Dfs*9 | Frame Shift Del (DEL) | VAF 65/504 reads (13%) | catalogued as rs746235140; called by pindel, varscan2
- LTBP1 | c.3802C>T p.R1268C (on ENST00000404816 / NM_206943.4; = p.R942C on NM_000627.4) | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs142670219; called by muse, mutect2, varscan2
- MAG | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 121/510 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62699490; called by muse, mutect2, varscan2
- MAMDC2 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 137/567 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV101015488; called by muse, mutect2, varscan2
- MUC16 | c.20509C>A p.P6837T | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV101198783; called by muse, varscan2
- MUC16 | c.20450C>T p.S6817F | Missense Mutation (SNP) | VAF 236/467 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); catalogued as COSV67446290; called by muse, varscan2
- MYH6 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 147/434 reads (34%) | catalogued as rs765861895, COSV59306908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.6471G>A p.R2157= | Splice Region (SNP) | VAF 278/279 reads (100%) | catalogued as COSV59148138, COSV59148223; called by muse, mutect2, varscan2
- MYO1G | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 163/815 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.405); catalogued as COSV99348635; called by muse, mutect2, varscan2
- MYPOP | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 260/507 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1397740594, COSV56193960; called by muse, mutect2, varscan2
- NCKAP5L | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 165/505 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs761149041; called by muse, mutect2, varscan2
- NEMF | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as COSV53594101; called by muse, mutect2, varscan2
- OPRK1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV55571867, COSV55573448; called by muse, mutect2, varscan2
- OR1E1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV59458371; called by muse, mutect2, varscan2
- OR4M1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 145/626 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60060003; called by muse, mutect2, varscan2
- OR52A1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100200444; called by muse, mutect2, varscan2
- OR5H1 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 289/594 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV100641577; called by muse, varscan2
- ORC4 | c.324A>C p.K108N | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs774417373; called by muse, mutect2, varscan2
- OTOGL | c.3952C>T p.P1318S (on ENST00000547103; = p.P1309S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs777012018, COSV72006661; called by muse, mutect2, varscan2
- OTOGL | c.5807G>A p.G1936E (on ENST00000547103; = p.G1927E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1371314789, COSV54021411, COSV54024952; called by muse, mutect2, varscan2
- OTOGL | c.5983C>T p.R1995* (on ENST00000547103; = p.R1986* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 192/307 reads (63%) | catalogued as rs779580098, COSV54020830; called by muse, mutect2, varscan2
- OVCH1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 166/254 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0.341); catalogued as rs748653263; called by muse, mutect2, varscan2
- PAK5 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 491/644 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs942131023, COSV62025855; called by muse, mutect2, varscan2
- PATZ1 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV56743711; called by muse, mutect2, varscan2
- PCDHA8 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 162/508 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as rs1554139058; called by muse, mutect2, varscan2
- PDE4DIP | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 123/534 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs782271941, COSV57674820; called by muse, mutect2, varscan2
- PHC3 | c.2164C>T p.R722C (on ENST00000494943 / NM_001308116.2; = p.R734C on NM_024947.4) | Missense Mutation (SNP) | VAF 152/231 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs777912781; called by muse, mutect2, varscan2
- PIK3C2A | c.4882G>C p.V1628L | Missense Mutation (SNP) | VAF 86/164 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs188004065; called by muse, mutect2, varscan2
- PKD1L3 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs866553574; called by muse, varscan2
- PKD2L1 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as COSV58396270, COSV58399396; called by muse, mutect2, varscan2
- PLXNC1 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs760717500, COSV51570639; called by muse, mutect2, varscan2
- PPIG | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs771655966; called by muse, mutect2
- PPP1R21 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 170/254 reads (67%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.898); catalogued as COSV99682831; called by muse, mutect2, varscan2
- PPP6R2 | c.2614G>A p.D872N (on ENST00000216061 / NM_001365836.1; = p.D838N on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/425 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99323947; called by muse, mutect2, varscan2
- PRR36 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 160/648 reads (25%) | SIFT tolerated, low confidence (0.14); catalogued as rs1216082930, COSV73401672; called by muse, mutect2, varscan2
- PSD3 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs753810304, COSV54075313; called by muse, mutect2, varscan2
- PSG6 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 233/503 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV51832255, COSV51834250; called by muse, mutect2, varscan2
- PSKH2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs747887278; called by muse, mutect2, varscan2
- RGMB | c.781G>A p.V261M (on ENST00000513185 / NM_001366508.1; = p.V302M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.25); catalogued as rs371130624, COSV57566269; called by muse, mutect2, varscan2
- RHPN1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 101/624 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs368151505; called by muse, mutect2, varscan2
- ROBO2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 241/373 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs567065372, COSV59896989; called by muse, mutect2, varscan2
- RP1L1 | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs367582741; called by muse, mutect2, varscan2
- RPTN | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1019810114, COSV60166727; called by muse, mutect2, varscan2
- SDE2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 90/539 reads (17%) | catalogued as rs771250921; called by muse, varscan2
- SELENOP | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 245/379 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV104423386; called by muse, mutect2, varscan2
- SEMA5B | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 224/335 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as rs770791208, COSV52104792; called by muse, mutect2, varscan2
- SETD1A | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs1490780571; called by muse, mutect2, varscan2
- SIAH3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 215/840 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV68552525; called by muse, mutect2, varscan2
- SIGLEC9 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 121/513 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.184); catalogued as rs756679145; called by muse, mutect2, varscan2
- SIMC1 | c.1952C>T p.S651F (on ENST00000443967 / NM_001308196.1; = p.S236F on NM_198567.5) | Missense Mutation (SNP) | VAF 250/411 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1330732067, COSV57908145; called by muse, mutect2, varscan2
- SLC16A9 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 132/238 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1410748605; called by muse, mutect2, varscan2
- SLC2A7 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as rs1445881119, COSV68901831; called by muse, mutect2, varscan2
- SLC5A5 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 146/599 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55832983; called by muse, mutect2
- SMG6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 170/363 reads (47%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs756932495, COSV53971149; called by muse, mutect2, varscan2
- SNAP47 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 438/614 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs143073539, COSV100247811; called by muse, mutect2, varscan2
- SPATA20 | c.550C>T p.P184S (on ENST00000356488 / NM_001258372.1; = p.P200S on NM_022827.4) | Missense Mutation (SNP) | VAF 554/779 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs923736431, COSV50068701; called by muse, mutect2
- SPATA31A7 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 173/1102 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1224647061; called by muse, mutect2, varscan2
- SPEN | c.6671A>G p.N2224S | Missense Mutation (SNP) | VAF 177/361 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs765138549; called by muse, mutect2, varscan2
- SRSF1 | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV51964410; called by mutect2, varscan2
- STOML3 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 471/471 reads (100%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767011238, COSV65512113; called by muse, mutect2, varscan2
- TBC1D22A | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1194794161; called by muse, mutect2, varscan2
- TECPR1 | c.3089C>T p.S1030F | Missense Mutation (SNP) | VAF 304/520 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs754787326; called by muse, mutect2, varscan2
- TECRL | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs866186058, COSV101169095; called by muse, mutect2, varscan2
- TJP3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 154/642 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs759077725; called by muse, mutect2, varscan2
- TMEM229A | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 126/664 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1328527094; called by muse, mutect2, varscan2
- TNNT2 | c.411C>T p.I137= | Splice Region (SNP) | VAF 258/360 reads (72%) | catalogued as rs727504322, CS1010370, COSV52660783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC18 | c.8314G>T p.V2772L | Missense Mutation (SNP) | VAF 138/772 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60308426; called by mutect2, varscan2
- TPTE2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 381/381 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs140148307; called by muse, mutect2, varscan2
- TRABD2B | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 147/300 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380108553; called by muse, mutect2, varscan2
- TSR1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 154/293 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs759910186; called by muse, mutect2, varscan2
- TTN | c.27164C>T p.S9055F (on ENST00000591111; = p.S8128F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 293/428 reads (68%) | PolyPhen possibly damaging (0.66); catalogued as COSV59863700; called by muse, mutect2, varscan2
- USP6 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.02); catalogued as rs749335334, COSV100003075; called by muse, mutect2, varscan2
- VWDE | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 222/530 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs1322400687, COSV51730634; called by muse, mutect2, varscan2
- WDHD1 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs774160091; called by muse, mutect2, varscan2
- WNT16 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 171/762 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs377091676; called by muse, mutect2, varscan2
- XIRP2 | c.2017C>T p.Q673* (on ENST00000628543; = p.Q848* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 240/368 reads (65%) | catalogued as COSV54715874, COSV54726456; called by muse, mutect2, varscan2
- ZNF365 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 139/276 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs780419322, COSV67925207; called by muse, mutect2, varscan2
- ZNF479 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 115/377 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV100482749, COSV58643985; called by muse, mutect2, varscan2
- ZNF490 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 227/483 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); catalogued as COSV61007741; called by muse, mutect2, varscan2
- ZNF536 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 349/723 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs765534247, COSV62826758; called by muse, mutect2, varscan2
- ZNF543 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100386805; called by muse, mutect2
- ZNF556 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 141/540 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1435609199; called by muse, mutect2, varscan2
- ZNF782 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 125/563 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001164; called by mutect2, varscan2
- ZNF783 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.314); catalogued as rs1202758829; called by muse, mutect2, varscan2
- ZNF804A | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56449169; called by muse, mutect2, varscan2
- ZNF814 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 287/585 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV71381805; called by muse, mutect2, varscan2
- ZXDA | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 195/399 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145718544; called by muse, mutect2, varscan2
- ABCA12 | c.7594_7599del p.V2532_A2533del (on ENST00000272895 / NM_173076.3; = p.V2214_A2215del on NM_015657.3) | In Frame Del (DEL) | VAF 80/366 reads (22%) | called by mutect2, pindel, varscan2
- ABCB11 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 304/430 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC3 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 189/709 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC245033.1 | c.1401A>T p.E467D | Missense Mutation (SNP) | VAF 147/632 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ACAN | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 231/475 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACE | c.3504G>A p.A1168= | Splice Region (SNP) | VAF 91/362 reads (25%) | called by muse, mutect2, varscan2
- ACOT6 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAM7 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRA1 | c.402-1G>A p.X134_splice | Splice Site (SNP) | VAF 101/225 reads (45%) | called by muse, mutect2, varscan2
- ADGRD2 | c.2490G>A p.W830* | Nonsense Mutation (SNP) | VAF 315/677 reads (47%) | called by muse, mutect2, varscan2
- AKAP11 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.8555C>T p.S2852F | Missense Mutation (SNP) | VAF 233/376 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALOX15B | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 168/321 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ANKLE2 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 162/505 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANO9 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 128/308 reads (42%) | called by muse, mutect2, varscan2
- ANP32B | c.374T>G p.V125G | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANXA7 | c.952C>A p.H318N (on ENST00000372919 / NM_001320880.2; = p.H296N on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- AP3B1 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP26 | c.395dup p.K133Efs*3 | Frame Shift Ins (INS) | VAF 56/207 reads (27%) | called by mutect2, pindel, varscan2
- ASPA | c.702T>A p.D234E | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAS3 | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 238/308 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- BCL6 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 317/491 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BPIFA1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 106/666 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- BTNL8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 189/313 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf141 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 461/621 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- C2CD4D | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 210/747 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.112); called by muse, varscan2
- C2orf16 | c.2543C>A p.P848H | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CACNA2D3 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CAPRIN2 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- CASP14 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 149/290 reads (51%) | called by muse, mutect2, varscan2
- CATSPER4 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 92/194 reads (47%) | called by muse, mutect2, varscan2
- CBLN4 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 132/666 reads (20%) | called by muse, mutect2, varscan2
- CCDC63 | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 181/282 reads (64%) | called by muse, mutect2, varscan2
- CCDC68 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 260/261 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CCDC7 | c.1537_1538del p.S513Ffs*3 | Frame Shift Del (DEL) | VAF 48/251 reads (19%) | called by pindel, varscan2
- CD9 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CLDN16 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 188/284 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CLPP | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLSTN2 | c.1780C>G p.P594A | Missense Mutation (SNP) | VAF 26/473 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLTC | c.3999G>T p.R1333S | Missense Mutation (SNP) | VAF 50/376 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.173); called by mutect2, varscan2
- CNGA3 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.82); called by muse, varscan2
- COG1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 289/372 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, varscan2
- COG1 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 296/380 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, varscan2
- CORO6 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 276/788 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CPNE8 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 144/411 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CREB5 | c.931C>T p.H311Y (on ENST00000357727 / NM_182898.4; = p.H304Y on NM_004904.3) | Missense Mutation (SNP) | VAF 505/1172 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CUX2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DCLK1 | c.960T>G p.S320R | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- DCLRE1A | c.992A>T p.D331V | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.141); called by mutect2, varscan2
- DCLRE1A | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DLEC1 | c.1762G>C p.G588R | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DSCAML1 | c.2646G>A p.W882* (on ENST00000321322; = p.W822* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 359/359 reads (100%) | called by muse, mutect2, varscan2
- DYNC1LI2 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCC1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 164/512 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EFHB | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ENPP1 | c.747del p.R249Sfs*26 | Frame Shift Del (DEL) | VAF 70/272 reads (26%) | called by mutect2, pindel*, varscan2
- ERVV-2 | c.1577T>C p.F526S | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ETV2 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 176/642 reads (27%) | called by muse, mutect2, varscan2
- EXOC3L2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 359/752 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EXOC4 | c.2003G>C p.R668T | Missense Mutation (SNP) | VAF 92/482 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM163B | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 125/600 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, varscan2
- FAM193B | c.2198_2199del p.V733Afs*48 | Frame Shift Del (DEL) | VAF 136/438 reads (31%) | called by pindel, varscan2
- FASTKD3 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- FBXL16 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 173/492 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- FBXL6 | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 32/730 reads (4%) | called by muse, mutect2
- FLRT2 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 135/439 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- FOXA2 | c.947G>C p.R316P (on ENST00000377115 / NM_153675.3; = p.R322P on NM_021784.5) | Missense Mutation (SNP) | VAF 121/679 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FSD2 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 139/516 reads (27%) | called by muse, mutect2, varscan2
- GCKR | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 203/303 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- GEN1 | c.2382T>G p.S794R | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GGA1 | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GGT1 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 127/505 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GIPC3 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 132/593 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- GJA8 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 414/575 reads (72%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GLRX | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 176/286 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- GPNMB | c.1664G>A p.G555E (on ENST00000381990 / NM_001005340.2; = p.G543E on NM_002510.3) | Missense Mutation (SNP) | VAF 118/543 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GTF3C2 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- HAUS6 | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 239/245 reads (98%) | called by muse, mutect2, varscan2
- HDAC9 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 115/548 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HERC5 | c.1753T>A p.C585S | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HGD | c.1280G>T p.W427L | Missense Mutation (SNP) | VAF 129/454 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIF3A | c.341G>A p.S114N (on ENST00000377670 / NM_152795.4; = p.S112N on NM_152794.4) | Missense Mutation (SNP) | VAF 103/489 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- HOXB3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- HOXD3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 174/561 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF3 | c.1799G>T p.R600L (on ENST00000369486 / NM_001007237.3; = p.R620L on NM_001542.4) | Missense Mutation (SNP) | VAF 170/694 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.356); called by mutect2, varscan2
- IL17RA | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 612/613 reads (100%) | called by muse, mutect2, varscan2
- INTS8 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 135/206 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ITGAE | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ITGAL | c.1698T>A p.S566R | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ITLN2 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 91/521 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- JAK2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 87/87 reads (100%) | called by muse, mutect2, varscan2
- JMJD1C | c.6724T>A p.F2242I | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNB2 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 326/503 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KCNQ2 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 327/595 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF16B | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 24/551 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2
- KRT37 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 240/534 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- KRTAP10-3 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 238/1010 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LOXHD1 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 153/436 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- LRRC9 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LRRK1 | c.2381C>A p.P794Q | Missense Mutation (SNP) | VAF 136/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRTM2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MACF1 | c.7687C>T p.P2563S | Missense Mutation (SNP) | VAF 97/207 reads (47%) | called by muse, mutect2, varscan2
- MAGEB10 | c.505A>C p.K169Q | Missense Mutation (SNP) | VAF 409/410 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MAP1S | c.119-1G>T p.X40_splice | Splice Site (SNP) | VAF 69/333 reads (21%) | called by muse, mutect2, varscan2
- MATN4 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 98/501 reads (20%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MCTP2 | c.1668G>A p.W556* | Nonsense Mutation (SNP) | VAF 330/330 reads (100%) | called by muse, mutect2, varscan2
- MDGA1 | c.385C>T p.L129= | Splice Region (SNP) | VAF 180/278 reads (65%) | called by muse, mutect2, varscan2
- MEF2C | c.739_742dup p.M248Rfs*4 | Frame Shift Ins (INS) | VAF 94/344 reads (27%) | called by mutect2, pindel, varscan2
- MEGF10 | c.2715T>A p.D905E | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MIDN | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MRAP2 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 435/437 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRC2 | c.3395A>G p.Y1132C | Missense Mutation (SNP) | VAF 409/920 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MROH2B | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 194/306 reads (63%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTTP | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC2 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0.01); called by muse, mutect2
- MUC4 | c.7108C>T p.P2370S | Missense Mutation (SNP) | VAF 208/1830 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MYO10 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 452/599 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.211); called by muse, mutect2
- MYO18A | c.3013A>C p.M1005L | Missense Mutation (SNP) | VAF 171/700 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYOM1 | c.4539G>T p.Q1513H | Missense Mutation (SNP) | VAF 135/413 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYOT | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 167/605 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MYT1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 157/868 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MZF1 | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 230/923 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NLRP13 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 158/633 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NSFL1C | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 304/408 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OGDHL | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 194/331 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2T34 | c.671_672insATCTG p.L225Sfs*11 | Frame Shift Ins (INS) | VAF 190/857 reads (22%) | called by mutect2, pindel*, varscan2*
- PABPC4 | c.1898C>A p.A633D | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2
- PARP12 | c.1463G>T p.W488L | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PARP4 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDE1C | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 101/550 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PHF12 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 153/673 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PIK3CG | c.1850G>T p.W617L | Missense Mutation (SNP) | VAF 126/682 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3R6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.2864C>T p.S955F | Missense Mutation (SNP) | VAF 127/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PKD1L1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 28/647 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.036); called by muse, mutect2
- PLEKHA5 | c.3153G>C p.E1051D | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB1 | c.5517C>A p.Y1839* | Nonsense Mutation (SNP) | VAF 112/340 reads (33%) | called by mutect2, varscan2
- PLXND1 | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 311/482 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- POU4F3 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 137/438 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R3A | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 78/582 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP2R5E | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 134/403 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRKCSH | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 174/691 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PSMB9 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 256/395 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PSME4 | c.4345G>T p.E1449* | Nonsense Mutation (SNP) | VAF 34/502 reads (7%) | called by muse, mutect2
- PTCHD3 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PTPRC | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 349/474 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRT | c.1308G>C p.E436D | Missense Mutation (SNP) | VAF 135/664 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PXDN | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 150/458 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RABGAP1L | c.943A>T p.I315F | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RBM12 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 115/529 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- RCN3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 276/517 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RCN3 | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 270/509 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- REPIN1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 186/877 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RGL1 | c.382G>A p.D128N (on ENST00000360851 / NM_001297672.2; = p.D163N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RHEB | c.333-1_336del p.X111_splice | Splice Site (DEL) | VAF 80/367 reads (22%) | called by mutect2, pindel, varscan2
- RIPK2 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 165/457 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- RNF213 | c.12283C>A p.L4095I | Missense Mutation (SNP) | VAF 381/519 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- RP1 | c.3256C>A p.L1086M | Missense Mutation (SNP) | VAF 138/270 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.07); called by mutect2, varscan2
- RSBN1L | c.1846T>C p.F616L | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RWDD2B | c.502del p.R168Efs*40 | Frame Shift Del (DEL) | VAF 94/626 reads (15%) | called by mutect2, pindel, varscan2
- RYR1 | c.15061G>A p.D5021N | Missense Mutation (SNP) | VAF 215/491 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- RYR2 | c.8299-1G>A p.X2767_splice | Splice Site (SNP) | VAF 64/249 reads (26%) | called by muse, mutect2, varscan2
- SCAF4 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 203/410 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCARF1 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 207/476 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3B | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); called by muse, mutect2
- SEPTIN11 | c.767C>G p.P256R | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB10 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SH3BP2 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHROOM4 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 196/393 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SI | c.4564G>A p.G1522R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC7 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 36/840 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2
- SLC1A1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC22A9 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC25A46 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 113/450 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC36A3 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC46A1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 163/636 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- SREBF2 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 342/342 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRPK1 | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- STARD8 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 435/436 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK11IP | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 218/353 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- STRN | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- STXBP5 | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 317/318 reads (100%) | called by muse, mutect2, varscan2
- TACC2 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 222/440 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TBK1 | c.1280G>C p.R427T | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TENM2 | c.7335G>A p.W2445* (on ENST00000518659 / NM_001122679.2; = p.W2206* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 15/510 reads (3%) | called by muse, mutect2
- TM4SF19 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC5 | c.452C>A p.T151K | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); called by muse, mutect2
- TNFRSF11A | c.78G>A p.V26= | Splice Region (SNP) | VAF 127/384 reads (33%) | called by muse, mutect2, varscan2
- TRAV3 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 268/424 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TRIM66 | c.2068C>A p.Q690K | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRMT10C | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRUB1 | c.845C>G p.P282R | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.082); called by muse, mutect2
- TTC21A | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 268/428 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- TTN | c.76852G>A p.D25618N (on ENST00000591111; = p.D18194N on NM_003319.4) | Missense Mutation (SNP) | VAF 276/436 reads (63%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TXNDC17 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP43 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 235/489 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR87 | c.5969C>A p.P1990Q | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- WNT5B | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 189/617 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- XDH | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 226/346 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZC3H7A | c.2350del p.C784Vfs*22 | Frame Shift Del (DEL) | VAF 75/322 reads (23%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.4058C>A p.A1353D | Missense Mutation (SNP) | VAF 164/451 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF195 | c.1433G>C p.C478S (on ENST00000399602 / NM_001130520.3; = p.C406S on NM_007152.5) | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF341 | c.2185C>T p.H729Y (on ENST00000375200 / NM_001282935.1; = p.H722Y on NM_032819.4) | Missense Mutation (SNP) | VAF 699/1054 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZNF468 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF469 | c.6596C>T p.S2199F (on ENST00000437464; = p.S2227F on NM_001367624.2) | Missense Mutation (SNP) | VAF 531/532 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZNF492 | c.429T>A p.C143* | Nonsense Mutation (SNP) | VAF 104/472 reads (22%) | called by muse, mutect2, varscan2
- ZNF512B | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 34/927 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ZNF629 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 528/529 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSWIM4 | c.1286_1288del p.R429del | In Frame Del (DEL) | VAF 118/538 reads (22%) | called by pindel, varscan2
- AACS | c.1212C>T p.L404= | Silent (SNP) | VAF 105/317 reads (33%) | called by muse, mutect2, varscan2
- AADACL4 | c.274C>T p.L92= | Silent (SNP) | VAF 163/325 reads (50%) | called by muse, mutect2, varscan2
- ABCB5 | c.2250T>C p.Y750= (on ENST00000404938 / NM_001163941.2; = p.Y305= on NM_178559.6) | Silent (SNP) | VAF 58/376 reads (15%) | called by muse, mutect2, varscan2
- ACMSD | c.129G>A p.G43= | Silent (SNP) | VAF 125/431 reads (29%) | called by muse, mutect2, varscan2
- ACSBG1 | c.1266C>A p.P422= | Silent (SNP) | VAF 98/394 reads (25%) | called by muse, mutect2, varscan2
- ACTR1B | c.222C>T p.P74= | Silent (SNP) | VAF 114/390 reads (29%) | called by muse, mutect2, varscan2
- ADAM22 | c.477G>A p.G159= | Silent (SNP) | VAF 200/336 reads (60%) | called by muse, mutect2, varscan2
- ALKBH4 | c.858G>T p.L286= | Silent (SNP) | VAF 183/700 reads (26%) | called by muse, mutect2, varscan2
- ANKS1A | c.585G>A p.L195= | Silent (SNP) | VAF 278/442 reads (63%) | called by muse, varscan2
- ANPEP | c.2520C>T p.I840= | Silent (SNP) | VAF 410/410 reads (100%) | catalogued as COSV55596194; called by muse, mutect2, varscan2
- AP3B1 | c.219G>A p.G73= | Silent (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- APC2 | c.6207C>A p.G2069= | Silent (SNP) | VAF 201/649 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.1041C>T p.T347= | Silent (SNP) | VAF 129/967 reads (13%) | called by muse, mutect2, varscan2
- BCAS3 | c.1227G>A p.Q409= | Silent (SNP) | VAF 243/315 reads (77%) | called by muse, mutect2, varscan2
- C1orf198 | c.408C>T p.S136= | Silent (SNP) | VAF 85/442 reads (19%) | catalogued as rs763326339, COSV64175183; called by muse, mutect2, varscan2
- C2orf16 | c.3609C>T p.S1203= | Silent (SNP) | VAF 258/368 reads (70%) | called by muse, mutect2, varscan2
- CC2D1A | c.1191C>A p.A397= | Silent (SNP) | VAF 155/580 reads (27%) | called by muse, mutect2, varscan2
- CCDC114 | c.1527C>G p.A509= | Silent (SNP) | VAF 192/733 reads (26%) | called by muse, mutect2, varscan2
- CCDC88A | c.3613T>C p.L1205= | Silent (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- CCL27 | c.249C>A p.P83= | Silent (SNP) | VAF 126/244 reads (52%) | called by muse, mutect2, varscan2
- CD1E | c.834G>A p.G278= | Silent (SNP) | VAF 401/544 reads (74%) | catalogued as rs775859149; called by muse, mutect2, varscan2
- CD5L | c.993G>T p.G331= | Silent (SNP) | VAF 137/562 reads (24%) | catalogued as rs138607635; called by muse, mutect2, varscan2
- CEBPB | c.240G>A p.E80= | Silent (SNP) | VAF 129/771 reads (17%) | catalogued as rs1353144921; called by muse, mutect2, varscan2
- CHAF1A | c.2292A>G p.G764= | Silent (SNP) | VAF 110/685 reads (16%) | catalogued as rs1292763200; called by muse, mutect2, varscan2
- CLDN4 | c.264C>T p.I88= | Silent (SNP) | VAF 401/1005 reads (40%) | called by muse, mutect2, varscan2
- COBLL1 | c.2655C>A p.P885= (on ENST00000392717; = p.P847= on NM_014900.5) | Silent (SNP) | VAF 138/393 reads (35%) | called by muse, mutect2, varscan2
- COL28A1 | c.2964C>T p.L988= | Silent (SNP) | VAF 79/518 reads (15%) | catalogued as rs367640726; called by muse, mutect2, varscan2
- CORO6 | c.129C>T p.N43= | Silent (SNP) | VAF 281/792 reads (35%) | called by muse, mutect2, varscan2
- CRB2 | c.411C>T p.G137= | Silent (SNP) | VAF 199/439 reads (45%) | called by muse, mutect2, varscan2
- CRISP3 | c.25C>T p.L9= | Silent (SNP) | VAF 242/243 reads (100%) | catalogued as rs1184322804; called by muse, mutect2, varscan2
- CRMP1 | c.456G>T p.L152= | Silent (SNP) | VAF 106/210 reads (50%) | catalogued as rs1204382155, COSV100271967; called by muse, mutect2, varscan2
- CTNNA2 | c.213C>T p.F71= | Silent (SNP) | VAF 115/397 reads (29%) | catalogued as COSV63563666; called by muse, mutect2, varscan2
- CTTNBP2 | c.4488G>A p.R1496= | Silent (SNP) | VAF 130/453 reads (29%) | catalogued as rs1184959360; called by muse, mutect2, varscan2
- CYSLTR2 | c.204G>A p.K68= | Silent (SNP) | VAF 125/520 reads (24%) | called by muse, mutect2, varscan2
- DACT1 | c.1422C>T p.S474= | Silent (SNP) | VAF 325/514 reads (63%) | catalogued as COSV100242184; called by muse, mutect2
- DACT2 | c.2295G>A p.P765= | Silent (SNP) | VAF 11/376 reads (3%) | catalogued as rs1342571402; called by muse, mutect2
- DCAF12L1 | c.375G>A p.V125= | Silent (SNP) | VAF 188/376 reads (50%) | called by muse, varscan2
- DGCR8 | c.1836C>A p.T612= | Silent (SNP) | VAF 246/377 reads (65%) | catalogued as COSV61227230; called by muse, mutect2, varscan2
- DMBT1 | c.2346C>T p.A782= | Silent (SNP) | VAF 315/573 reads (55%) | called by muse, mutect2, varscan2
- DSC1 | c.885C>T p.S295= | Silent (SNP) | VAF 321/321 reads (100%) | called by muse, mutect2, varscan2
- DSG2 | c.582G>A p.S194= | Silent (SNP) | VAF 212/352 reads (60%) | catalogued as rs748768578, COSV55198230; called by muse, mutect2, varscan2
- ECM1 | c.1209C>A p.P403= | Silent (SNP) | VAF 175/642 reads (27%) | called by muse, mutect2, varscan2
- EHD2 | c.436C>T p.L146= | Silent (SNP) | VAF 79/323 reads (24%) | called by muse, mutect2, varscan2
- FAM131C | c.711C>A p.P237= | Silent (SNP) | VAF 101/659 reads (15%) | catalogued as rs1419396519; called by muse, mutect2, varscan2
- FAM135B | c.3171C>T p.F1057= | Silent (SNP) | VAF 234/537 reads (44%) | catalogued as COSV52739774; called by muse, mutect2, varscan2
- FCRL4 | c.1204C>T p.L402= | Silent (SNP) | VAF 384/548 reads (70%) | called by muse, mutect2, varscan2
- FER1L5 | c.4995C>T p.F1665= (on ENST00000623019; = p.F1638= on NM_001293083.2) | Silent (SNP) | VAF 89/267 reads (33%) | catalogued as COSV67606878; called by muse, mutect2, varscan2
- FLT3LG | c.636G>A p.R212= | Silent (SNP) | VAF 340/697 reads (49%) | catalogued as rs755546964, COSV52618356; called by muse, mutect2, varscan2
- FOXG1 | c.1074C>T p.T358= | Silent (SNP) | VAF 176/540 reads (33%) | catalogued as COSV57400166; called by muse, mutect2, varscan2
- FXYD7 | c.6G>A p.A2= | Silent (SNP) | VAF 266/605 reads (44%) | called by muse, mutect2, varscan2
- FYB2 | c.30G>A p.K10= | Silent (SNP) | VAF 87/168 reads (52%) | catalogued as rs773017954; called by muse, mutect2, varscan2
- GADL1 | c.610C>T p.L204= | Silent (SNP) | VAF 170/284 reads (60%) | called by muse, mutect2, varscan2
- GDF5 | c.1026C>T p.F342= | Silent (SNP) | VAF 318/853 reads (37%) | called by muse, mutect2, varscan2
- GDPD5 | c.468C>T p.S156= | Silent (SNP) | VAF 261/261 reads (100%) | catalogued as rs771632107, COSV61130224; called by muse, mutect2, varscan2
- GOLGA8Q | c.645G>A p.Q215= | Silent (SNP) | VAF 278/578 reads (48%) | catalogued as rs1280896561; called by muse, mutect2, varscan2
- GRIN2B | c.1149C>T p.S383= | Silent (SNP) | VAF 98/274 reads (36%) | catalogued as rs774861400, COSV74205848; called by muse, mutect2, varscan2
- GRPR | c.348C>T p.I116= | Silent (SNP) | VAF 181/404 reads (45%) | called by muse, mutect2, varscan2
- GSTA3 | c.408C>T p.F136= | Silent (SNP) | VAF 226/226 reads (100%) | catalogued as COSV52980684; called by muse, varscan2
- H1-5 | c.213C>T p.A71= | Silent (SNP) | VAF 411/411 reads (100%) | catalogued as rs749604290, COSV100137744; called by muse, mutect2, varscan2
- H2AC13 | c.27C>G p.G9= | Silent (SNP) | VAF 294/300 reads (98%) | called by muse, mutect2, varscan2
- HABP2 | c.1639C>T p.L547= | Silent (SNP) | VAF 202/376 reads (54%) | catalogued as rs1053152690; called by muse, mutect2
- HDAC4 | c.714C>T p.D238= | Silent (SNP) | VAF 140/140 reads (100%) | called by muse, mutect2, varscan2
- HEG1 | c.2685A>T p.T895= | Silent (SNP) | VAF 305/450 reads (68%) | called by muse, mutect2, varscan2
- HIVEP1 | c.5283C>T p.H1761= | Silent (SNP) | VAF 233/357 reads (65%) | called by muse, mutect2, varscan2
- HMMR | c.1605A>G p.Q535= | Silent (SNP) | VAF 53/243 reads (22%) | catalogued as rs1311136159; called by muse, mutect2, varscan2
- HNRNPLL | c.1497G>A p.G499= | Silent (SNP) | VAF 79/260 reads (30%) | catalogued as rs759114614; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1179C>T p.S393= | Silent (SNP) | VAF 141/331 reads (43%) | called by muse, mutect2, varscan2
- IDUA | c.834C>T p.V278= | Silent (SNP) | VAF 338/338 reads (100%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.348C>T p.F116= | Silent (SNP) | VAF 178/484 reads (37%) | called by muse, mutect2
- IL37 | c.291C>T p.S97= | Silent (SNP) | VAF 158/261 reads (61%) | called by muse, mutect2, varscan2
- ITPKA | c.696T>C p.P232= | Silent (SNP) | VAF 193/386 reads (50%) | called by muse, mutect2, varscan2
- JPH1 | c.591C>T p.F197= | Silent (SNP) | VAF 370/570 reads (65%) | catalogued as COSV100646794; called by muse, mutect2, varscan2
- KCNJ3 | c.441C>T p.G147= | Silent (SNP) | VAF 36/536 reads (7%) | catalogued as COSV54539443; called by muse, mutect2
- KIAA0100 | c.5052A>G p.T1684= | Silent (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- KIAA1549 | c.4665G>C p.S1555= | Silent (SNP) | VAF 93/695 reads (13%) | called by muse, mutect2, varscan2
- KIF7 | c.360C>T p.V120= | Silent (SNP) | VAF 378/378 reads (100%) | catalogued as rs1287682022; called by muse, mutect2, varscan2
- KIR3DL2 | c.771G>A p.R257= | Silent (SNP) | VAF 138/522 reads (26%) | called by muse, mutect2, varscan2
- KL | c.288C>T p.H96= | Silent (SNP) | VAF 159/733 reads (22%) | catalogued as rs764495584; called by muse, mutect2, varscan2
- L3MBTL1 | c.549A>G p.P183= (on ENST00000418998 / NM_001377303.1; = p.P93= on NM_015478.7) | Silent (SNP) | VAF 441/603 reads (73%) | catalogued as rs1374649978; called by muse, mutect2, varscan2
- LRRC71 | c.273C>T p.F91= | Silent (SNP) | VAF 110/427 reads (26%) | catalogued as rs1456172955, COSV61656140; called by muse, mutect2, varscan2
- LTBP4 | c.66A>G p.A22= | Silent (SNP) | VAF 209/836 reads (25%) | called by muse, mutect2, varscan2
- LZTS2 | c.687C>T p.P229= | Silent (SNP) | VAF 224/400 reads (56%) | catalogued as rs1304577412; called by muse, mutect2, varscan2
- MAP3K11 | c.1644C>T p.S548= | Silent (SNP) | VAF 356/356 reads (100%) | catalogued as rs1192546017; called by muse, mutect2, varscan2
- MAS1 | c.612G>T p.L204= | Silent (SNP) | VAF 236/378 reads (62%) | catalogued as COSV53122034; called by muse, mutect2, varscan2
- MAST2 | c.1377C>T p.P459= | Silent (SNP) | VAF 106/235 reads (45%) | called by muse, mutect2, varscan2
- MDH1B | c.606G>A p.E202= | Silent (SNP) | VAF 157/470 reads (33%) | called by muse, mutect2, varscan2
- MNDA | c.627C>T p.N209= | Silent (SNP) | VAF 50/647 reads (8%) | catalogued as COSV100933336; called by muse, mutect2
- MUC16 | c.2628A>G p.Q876= | Silent (SNP) | VAF 228/458 reads (50%) | catalogued as rs373592887; called by muse, mutect2, varscan2
- MUC4 | c.12885C>T p.P4295= (on ENST00000463781 / NM_018406.7; = p.P59= on NM_004532.6) | Silent (SNP) | VAF 272/834 reads (33%) | called by muse, mutect2, varscan2
- MUC5AC | c.84G>A p.Q28= | Silent (SNP) | VAF 347/347 reads (100%) | catalogued as rs1225149562; called by muse, mutect2, varscan2
- MYBPC2 | c.1575C>T p.F525= | Silent (SNP) | VAF 174/374 reads (47%) | called by muse, mutect2, varscan2
- MYH7 | c.4413G>A p.Q1471= | Silent (SNP) | VAF 164/555 reads (30%) | catalogued as COSV62519235; called by muse, mutect2, varscan2
- MYO9A | c.7365C>T p.S2455= | Silent (SNP) | VAF 116/529 reads (22%) | called by muse, mutect2, varscan2
- MYOCD | c.1425C>T p.F475= | Silent (SNP) | VAF 203/410 reads (50%) | catalogued as COSV58513583; called by muse, mutect2, varscan2
- NBR1 | c.1332G>A p.V444= | Silent (SNP) | VAF 176/686 reads (26%) | catalogued as COSV100357826; called by muse, mutect2, varscan2
- NCKAP5L | c.1986G>T p.R662= | Silent (SNP) | VAF 164/505 reads (32%) | called by muse, mutect2, varscan2
- NEB | c.6255C>A p.P2085= | Silent (SNP) | VAF 133/423 reads (31%) | catalogued as COSV51459833; called by muse, mutect2, varscan2
- NIF3L1 | c.177C>T p.S59= (on ENST00000409020 / NM_001369444.1; = p.S32= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 281/455 reads (62%) | called by muse, mutect2, varscan2
- NIPA1 | c.900C>T p.T300= | Silent (SNP) | VAF 103/239 reads (43%) | catalogued as rs1363040527, COSV61679570; called by muse, mutect2, varscan2
- NLRP13 | c.1380C>T p.F460= | Silent (SNP) | VAF 154/681 reads (23%) | catalogued as COSV100738433, COSV99048651; called by muse, mutect2, varscan2
- NLRP3 | c.2889G>C p.L963= | Silent (SNP) | VAF 81/462 reads (18%) | called by muse, mutect2, varscan2
- NUTM2F | c.2019G>A p.Q673= | Silent (SNP) | VAF 259/551 reads (47%) | called by muse, mutect2, varscan2
- OR13C5 | c.531C>T p.F177= | Silent (SNP) | VAF 123/446 reads (28%) | catalogued as COSV66165252; called by muse, mutect2, varscan2
- OR4C6 | c.634T>C p.L212= | Silent (SNP) | VAF 289/289 reads (100%) | called by muse, mutect2, varscan2
- OR6B1 | c.210G>A p.E70= | Silent (SNP) | VAF 395/677 reads (58%) | catalogued as COSV101281655, COSV68770432; called by muse, mutect2, varscan2
- PABPC4 | c.1899C>T p.A633= | Silent (SNP) | VAF 109/267 reads (41%) | called by muse, mutect2
- PCDH15 | c.4452C>T p.P1484= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as rs752602791, COSV57393082; called by muse, mutect2, varscan2
- PCDHA7 | c.1965G>A p.G655= | Silent (SNP) | VAF 273/407 reads (67%) | catalogued as rs782660367; called by muse, mutect2, varscan2
- PCSK5 | c.801T>A p.I267= | Silent (SNP) | VAF 295/586 reads (50%) | called by muse, mutect2, varscan2
- PEX11G | c.159C>T p.S53= | Silent (SNP) | VAF 131/613 reads (21%) | catalogued as rs748443977; called by muse, mutect2
- PKD1L1 | c.3885G>T p.L1295= | Silent (SNP) | VAF 90/536 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.720C>T p.P240= | Silent (SNP) | VAF 129/288 reads (45%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.2341T>C p.L781= | Silent (SNP) | VAF 247/247 reads (100%) | called by muse, mutect2, varscan2
- PLK3 | c.1566C>A p.P522= | Silent (SNP) | VAF 126/262 reads (48%) | called by muse, mutect2, varscan2
- PNPLA5 | c.1218C>T p.V406= | Silent (SNP) | VAF 174/531 reads (33%) | called by muse, mutect2, varscan2
- PPP1R12A | c.2220A>G p.Q740= | Silent (SNP) | VAF 110/369 reads (30%) | catalogued as rs1220651953; called by muse, mutect2, varscan2
- PRKDC | c.7383C>T p.F2461= | Silent (SNP) | VAF 138/292 reads (47%) | catalogued as rs761453930, COSV58044923; ClinVar: likely benign; called by muse, mutect2, varscan2
- PROX1 | c.1137T>G p.V379= | Silent (SNP) | VAF 172/573 reads (30%) | called by muse, mutect2, varscan2
- PTH2R | c.780C>T p.Y260= | Silent (SNP) | VAF 146/465 reads (31%) | called by muse, mutect2, varscan2
- PTPRQ | c.4726C>T p.L1576= (on ENST00000616559; = p.L1534= on NM_001145026.2) | Silent (SNP) | VAF 74/274 reads (27%) | catalogued as rs1332197593; called by muse, mutect2, varscan2
- QSOX2 | c.2022C>T p.F674= | Silent (SNP) | VAF 274/593 reads (46%) | catalogued as COSV100699781; called by muse, mutect2, varscan2
- RADIL | c.2265G>A p.Q755= | Silent (SNP) | VAF 184/819 reads (22%) | catalogued as rs541651809; called by muse, mutect2, varscan2
- RELN | c.9627C>T p.I3209= | Silent (SNP) | VAF 233/423 reads (55%) | catalogued as COSV58986456; called by muse, mutect2, varscan2
- RGS21 | c.15C>T p.C5= | Silent (SNP) | VAF 231/302 reads (76%) | catalogued as COSV69883498, COSV69883676; called by muse, varscan2
- RNF213 | c.12282T>A p.S4094= | Silent (SNP) | VAF 383/519 reads (74%) | called by muse, mutect2, varscan2
- RP1 | c.3894C>T p.F1298= | Silent (SNP) | VAF 105/227 reads (46%) | catalogued as COSV55115168; called by muse, mutect2, varscan2
- RP1L1 | c.4992G>A p.R1664= | Silent (SNP) | VAF 203/203 reads (100%) | catalogued as COSV101222904; called by muse, mutect2, varscan2
- RPTN | c.1851G>A p.G617= | Silent (SNP) | VAF 161/704 reads (23%) | called by muse, mutect2, varscan2
- S100A3 | c.273G>A p.K91= | Silent (SNP) | VAF 158/566 reads (28%) | called by muse, mutect2, varscan2
- SCN2A | c.3027G>A p.R1009= | Silent (SNP) | VAF 96/317 reads (30%) | called by muse, mutect2, varscan2
- SENP7 | c.165A>G p.E55= | Silent (SNP) | VAF 87/282 reads (31%) | catalogued as rs746707435; called by muse, mutect2, varscan2
- SH3TC1 | c.3144C>T p.S1048= | Silent (SNP) | VAF 193/194 reads (99%) | catalogued as rs142898849, COSV99795157; called by muse, mutect2, varscan2
- SI | c.615G>A p.R205= | Silent (SNP) | VAF 84/319 reads (26%) | catalogued as rs867555272, COSV52269599; called by muse, mutect2, varscan2
- SLC4A11 | c.2550C>T p.S850= | Silent (SNP) | VAF 149/594 reads (25%) | called by muse, mutect2, varscan2
- SLC4A2 | c.3325C>T p.L1109= | Silent (SNP) | VAF 103/406 reads (25%) | called by muse, mutect2, varscan2
- SLC51B | c.252G>A p.K84= | Silent (SNP) | VAF 157/704 reads (22%) | called by muse, mutect2, varscan2
- SLC6A16 | c.937C>T p.L313= | Silent (SNP) | VAF 98/389 reads (25%) | catalogued as rs1568533794; called by muse, mutect2, varscan2
- SLC6A4 | c.264C>T p.F88= | Silent (SNP) | VAF 114/541 reads (21%) | catalogued as rs1472045495; called by muse, mutect2, varscan2
- SLFN13 | c.951G>A p.K317= | Silent (SNP) | VAF 482/654 reads (74%) | called by muse, mutect2, varscan2
- SMG9 | c.759C>T p.T253= | Silent (SNP) | VAF 109/505 reads (22%) | called by muse, mutect2, varscan2
- SND1 | c.2616G>A p.Q872= | Silent (SNP) | VAF 207/373 reads (55%) | called by muse, mutect2, varscan2
- SNX21 | c.120G>A p.P40= | Silent (SNP) | VAF 191/977 reads (20%) | called by muse, mutect2, varscan2
- SOX10 | c.558C>T p.G186= | Silent (SNP) | VAF 165/579 reads (28%) | catalogued as rs542276568; called by muse, mutect2, varscan2
- SPATA31D4 | c.2109C>T p.I703= | Silent (SNP) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- SPATS2 | c.1080C>T p.T360= | Silent (SNP) | VAF 59/219 reads (27%) | called by muse, mutect2, varscan2
- SPTBN5 | c.466C>T p.L156= | Silent (SNP) | VAF 112/112 reads (100%) | called by muse, mutect2, varscan2
- SREBF2 | c.3114C>T p.T1038= | Silent (SNP) | VAF 346/346 reads (100%) | catalogued as rs148027800; called by muse, mutect2, varscan2
- SRGAP2 | c.2670T>C p.D890= (on ENST00000624873 / NM_001170637.4; = p.D891= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 160/699 reads (23%) | called by muse, mutect2, varscan2
- SV2B | c.1029C>A p.P343= | Silent (SNP) | VAF 84/347 reads (24%) | called by muse, mutect2, varscan2
- SYNE2 | c.13611C>T p.F4537= | Silent (SNP) | VAF 245/388 reads (63%) | catalogued as COSV59969487; called by muse, mutect2, varscan2
- TANC1 | c.2700C>T p.A900= | Silent (SNP) | VAF 115/364 reads (32%) | catalogued as rs759214261; called by muse, mutect2, varscan2
- TAS2R13 | c.501C>T p.F167= | Silent (SNP) | VAF 323/493 reads (66%) | called by muse, mutect2, varscan2
- TAX1BP1 | c.498G>A p.K166= | Silent (SNP) | VAF 93/471 reads (20%) | catalogued as rs530715505; called by muse, mutect2, varscan2
- TNS1 | c.3183G>A p.L1061= | Silent (SNP) | VAF 273/442 reads (62%) | called by muse, mutect2, varscan2
- TPRN | c.1266C>T p.F422= | Silent (SNP) | VAF 198/812 reads (24%) | called by muse, mutect2, varscan2
- TRAV3 | c.279C>T p.F93= | Silent (SNP) | VAF 271/433 reads (63%) | catalogued as rs370872134; called by muse, mutect2, varscan2
- TSPAN8 | c.393A>C p.T131= | Silent (SNP) | VAF 200/291 reads (69%) | called by muse, mutect2, varscan2
- TTN | c.43140C>T p.V14380= (on ENST00000591111; = p.V6956= on NM_003319.4) | Silent (SNP) | VAF 307/495 reads (62%) | called by muse, mutect2, varscan2
- UPF1 | c.249C>T p.I83= | Silent (SNP) | VAF 211/442 reads (48%) | called by muse, mutect2, varscan2
- VPS13B | c.7566C>T p.Y2522= | Silent (SNP) | VAF 101/327 reads (31%) | catalogued as COSV62154031; called by muse, mutect2, varscan2
- WDR6 | c.880C>A p.R294= | Silent (SNP) | VAF 291/450 reads (65%) | catalogued as rs546795438; called by muse, mutect2, varscan2
- WNK2 | c.2406C>T p.P802= | Silent (SNP) | VAF 169/641 reads (26%) | called by muse, mutect2, varscan2
- ZC3H6 | c.285C>T p.S95= | Silent (SNP) | VAF 88/285 reads (31%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.1173C>T p.F391= | Silent (SNP) | VAF 138/229 reads (60%) | called by muse, mutect2, varscan2
- ZNF365 | c.580C>T p.L194= | Silent (SNP) | VAF 165/305 reads (54%) | catalogued as COSV67925192; called by muse, mutect2, varscan2
- ZNF485 | c.918C>T p.A306= | Silent (SNP) | VAF 111/264 reads (42%) | called by muse, varscan2
- ZNF546 | c.921G>T p.G307= | Silent (SNP) | VAF 124/489 reads (25%) | catalogued as COSV61258703; called by mutect2, varscan2
- ZNF668 | c.450C>T p.G150= | Silent (SNP) | VAF 177/868 reads (20%) | catalogued as rs765786681; called by muse, mutect2, varscan2
- ZNF705G | c.870G>A p.G290= | Silent (SNP) | VAF 106/229 reads (46%) | catalogued as rs776589264; called by muse, varscan2
- ZNF804B | c.1293A>T p.A431= | Silent (SNP) | VAF 320/552 reads (58%) | catalogued as COSV60837783; called by muse, mutect2, varscan2
- ZSCAN1 | c.945C>T p.R315= | Silent (SNP) | VAF 169/726 reads (23%) | catalogued as rs370513764; called by muse, mutect2, varscan2
- AC244197.3 | c.*2413C>A | 3'UTR (SNP) | VAF 350/350 reads (100%) | called by muse, mutect2, varscan2
- ANK3 | c.2738+261A>G | Intron (SNP) | VAF 126/254 reads (50%) | called by muse, mutect2, varscan2
- C14orf177 | n.675G>T | RNA (SNP) | VAF 96/331 reads (29%) | catalogued as COSV57901813; called by mutect2, varscan2
- C5orf60 | n.33G>A | RNA (SNP) | VAF 93/484 reads (19%) | catalogued as rs1562391297; called by muse, mutect2, varscan2
- CRYBG2 | c.-92C>T | 5'UTR (SNP) | VAF 132/287 reads (46%) | called by muse, mutect2, varscan2
- CTC1 | chr17:8222916 G>A | 3'Flank (SNP) | VAF 149/266 reads (56%) | catalogued as rs560401736; called by muse, mutect2, varscan2
- ERBB3 | c.-1C>T | 5'UTR (SNP) | VAF 41/485 reads (8%) | catalogued as rs1417107248; called by muse, mutect2
- GPR137 | chr11:64284750 G>T | 5'Flank (SNP) | VAF 106/229 reads (46%) | catalogued as rs1325730018; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+30590C>T | Intron (SNP) | VAF 210/211 reads (100%) | called by muse, mutect2, varscan2
- MRPL46 | c.415+93T>C | Intron (SNP) | VAF 95/434 reads (22%) | called by muse, mutect2, varscan2
- NCR2 | c.644+871del | Intron (DEL) | VAF 76/294 reads (26%) | called by mutect2, pindel, varscan2
- PCK2 | chr14:24094086 G>A | 5'Flank (SNP) | VAF 85/279 reads (30%) | called by muse, mutect2, varscan2
- PTGDR | c.846+800C>T | Intron (SNP) | VAF 212/309 reads (69%) | called by muse, mutect2, varscan2
- RAB34 | c.-225T>A | 5'UTR (SNP) | VAF 86/658 reads (13%) | called by muse, mutect2, varscan2
- SORBS1 | c.2129-989C>T | Intron (SNP) | VAF 186/328 reads (57%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4153G>A | Intron (SNP) | VAF 80/290 reads (28%) | called by muse, mutect2, varscan2
